Somatic mutation profile of tumor specimen MP2PRT-PAPHVV-TBP1-A (aliquot MP2PRT-PAPHVV-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHVV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (979 days).
Specimen MP2PRT-PAPHVV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6e2fc7e-7e23-46eb-81ae-c882cf3ca634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHVV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHVV-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c01c7dac-3ddb-408f-a1c6-52489797a517

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 50/289 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 84/288 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 58/264 reads (22%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 63/385 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL4A6 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 54/391 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767259303; called by muse, mutect2, varscan2
- DNAH8 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1738248, COSV59464232; called by muse, mutect2, varscan2
- KMT2D | c.15541G>A p.G5181R | Missense Mutation (SNP) | VAF 146/410 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977209; called by muse, mutect2, varscan2
- RORC | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755871920, COSV59096609; called by muse, mutect2, varscan2
- VSTM2A | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 109/403 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56494221; called by muse, mutect2, varscan2
- DCUN1D3 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 148/340 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- HERC1 | c.3482_3483insGGAC p.V1162Dfs*20 | Frame Shift Ins (INS) | VAF 66/301 reads (22%) | called by pindel, varscan2
- NACA | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP6 | c.2498G>C p.C833S | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PTPRZ1 | c.6806T>C p.I2269T | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RASGRF2 | c.2775G>A p.W925* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- CDA | c.222C>T p.A74= | Silent (SNP) | VAF 53/355 reads (15%) | catalogued as rs781623943, COSV100906276; called by muse, mutect2, varscan2
- COL6A3 | c.5868C>T p.D1956= | Silent (SNP) | VAF 61/263 reads (23%) | catalogued as rs777508994, COSV55092276; called by muse, mutect2, varscan2
- CYP4F2 | c.1305G>A p.P435= | Silent (SNP) | VAF 118/276 reads (43%) | catalogued as rs377551326; called by muse, mutect2, varscan2
- KLF15 | c.348G>A p.K116= | Silent (SNP) | VAF 195/409 reads (48%) | called by muse, mutect2, varscan2
- NEO1 | c.3630A>G p.Q1210= | Silent (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
